MMRF case MMRF_1307 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e9873dce-bece-45d0-98d3-556e449f6e07

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.1 years (27,047 days); ISS stage: I; Days to last known disease status: 1,523 days (4.2 years); Days to last follow up: 1,523 days (4.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,142 days (3.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 11 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,142 days (3.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 2): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.091 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.14 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 49 g/L; Total Protein 7.7 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 93: M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.848 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 17.8 ×10⁹/L; Absolute Neutrophil 15.3 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 53 g/L; Total Protein 7.2 g/dL; Glucose 5.94 mmol/L.
- Day 189: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.911 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 282 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.994 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.927 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 378 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.903 mg/dL; Immunoglobulin G 6.29 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 422 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.941 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 5.28 mmol/L.
- Day 539: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.979 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 637 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.978 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.57 mmol/L.
- Day 728 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.916 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.806 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 809: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.803 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 991 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 7.23 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.12 mmol/L.
- Day 1,110 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.663 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 1.75 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 1,292: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.29 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 5.5 mmol/L.
- Day 1,474 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.945 mg/dL; Immunoglobulin G 8.8 g/L; Immunoglobulin A 1.77 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 1,523 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.821 mg/dL; Immunoglobulin G 8.8 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -5: Weight: 70 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1307_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1307_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
